Somatic mutation profile of tumor specimen MMRF_2641_1_BM_CD138pos (aliquot MMRF_2641_1_BM_CD138pos_T1_KHS5U_L13408) from MMRF case MMRF_2641, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.5 years (19,546 days).
Specimen MMRF_2641_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e32e615f-c663-459a-8884-98504b42ca9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2641_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2641_1_PB_WBC_C3_KHS5U_L13409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f402c8f4-1903-4783-b47c-3fc65db090cf

The open-access MAF lists 84 somatic variants for this specimen: 28 protein-altering or splice-affecting, 11 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 27, Missense Mutation 25, Silent 11, Intron 8, 3'Flank 4, 5'UTR 3, 5'Flank 3, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ABCB11 | c.2092C>T p.R698C | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs539087982; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BICRA | c.2909T>C p.I970T | Missense Mutation (SNP) | VAF 102/213 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs1387440132; called by muse, mutect2, varscan2
- CACNA1H | c.3845+1G>T p.X1282_splice | Splice Site (SNP) | VAF 7/95 reads (7%) | catalogued as COSV61988366; called by muse, mutect2
- CD5L | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as rs200131192, COSV63821183, COSV63822864; called by muse, mutect2, varscan2
- FBXW10 | c.1541A>G p.D514G | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1054623666; called by muse, mutect2, varscan2
- IGHV2-70 | c.330C>A p.D110E | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs571957876; called by muse, varscan2
- IGHV2-70D | c.305C>G p.T102R | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1310540287; called by muse, varscan2
- IGLV3-1 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs561948127; called by muse, mutect2, varscan2
- IGLV4-3 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.481); catalogued as rs576246152; called by muse, mutect2, varscan2
- KIAA0825 | c.2669C>T p.T890M | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as rs753994926; called by muse, mutect2, varscan2
- LPAR5 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.635); catalogued as COSV61692095; called by muse, mutect2, varscan2
- NIPAL1 | c.275G>A p.G92D | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55005769; called by muse, mutect2, varscan2
- RAB19 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1239263920; called by muse, mutect2, varscan2
- SCN10A | c.4766C>T p.A1589V | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs753004431, COSV71860872; called by muse, mutect2, varscan2
- ZNFX1 | c.381del p.W127Cfs*23 | Frame Shift Del (DEL) | VAF 73/160 reads (46%) | catalogued as COSV65580164; called by mutect2, pindel, varscan2
- ANKS1A | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BHLHE41 | c.304T>G p.L102V | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- BICC1 | c.2362A>C p.T788P | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1I | c.2883C>G p.S961R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.383); called by muse, mutect2
- ECM2 | c.1870C>A p.P624T | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV2-70D | c.308T>A p.M103K | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, varscan2
- KBTBD3 | c.700C>G p.L234V | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- MROH9 | c.1642G>T p.V548F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by mutect2, varscan2
- SLC6A14 | c.566A>C p.N189T | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT tolerated (0.34); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- TTN | c.5596G>A p.G1866S (on ENST00000591111; = p.G1820S on NM_003319.4) | Missense Mutation (SNP) | VAF 45/207 reads (22%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UGP2 | c.20-2_21del p.X7_splice | Splice Site (DEL) | VAF 109/405 reads (27%) | called by mutect2, pindel, varscan2
- WDFY3 | c.1813G>T p.D605Y | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ABCA1 | c.5631G>A p.R1877= | Silent (SNP) | VAF 24/86 reads (28%) | called by muse, mutect2, varscan2
- ADGRD1 | c.1908C>G p.A636= | Silent (SNP) | VAF 84/210 reads (40%) | catalogued as rs773163978, COSV55456377; called by muse, mutect2, varscan2
- ADGRV1 | c.570C>G p.G190= | Silent (SNP) | VAF 116/177 reads (66%) | called by muse, mutect2, varscan2
- COL6A3 | c.4218G>A p.T1406= | Silent (SNP) | VAF 171/247 reads (69%) | catalogued as rs756249024, COSV55096502; called by muse, mutect2, varscan2
- EGR1 | c.103C>T p.L35= | Silent (SNP) | VAF 170/285 reads (60%) | catalogued as rs558452520, COSV53520131; called by muse, mutect2, varscan2
- H4C5 | c.183G>A p.V61= | Silent (SNP) | VAF 99/299 reads (33%) | called by muse, mutect2, varscan2
- HMGXB4 | c.654G>C p.A218= | Silent (SNP) | VAF 50/149 reads (34%) | catalogued as COSV53333688; called by muse, mutect2, varscan2
- PTCHD3 | c.345C>T p.H115= | Silent (SNP) | VAF 67/126 reads (53%) | catalogued as rs1339793112; called by muse, mutect2, varscan2
- TPTE | c.759T>A p.S253= (on ENST00000618007 / NM_199261.4; = p.S235= on NM_199259.4) | Silent (SNP) | VAF 11/365 reads (3%) | called by muse, mutect2
- USP4 | c.684C>G p.T228= | Silent (SNP) | VAF 134/203 reads (66%) | catalogued as COSV99649299; called by muse, mutect2, varscan2
- ZNF429 | c.282T>G p.S94= | Silent (SNP) | VAF 43/230 reads (19%) | called by muse, mutect2, varscan2
- AC022826.2 | c.442+25266T>C | Intron (SNP) | VAF 14/198 reads (7%) | called by muse, mutect2
- ANKS1B | c.3672+6107G>A | Intron (SNP) | VAF 3/50 reads (6%) | catalogued as rs1057339360; called by muse, mutect2
- ARHGAP18 | c.*916T>A | 3'UTR (SNP) | VAF 72/116 reads (62%) | catalogued as COSV63763623; called by muse, varscan2
- B3GALT5-AS1 | chr21:39598047 T>G | 3'Flank (SNP) | VAF 32/111 reads (29%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021529 A>T | 5'Flank (SNP) | VAF 32/88 reads (36%) | called by muse, varscan2
- BCL7A | chr12:122021587 G>A | 5'Flank (SNP) | VAF 24/58 reads (41%) | catalogued as COSV55851056; called by muse, varscan2
- BCLAF3 | c.*865T>A | 3'UTR (SNP) | VAF 25/31 reads (81%) | called by muse, mutect2, varscan2
- C10orf67 | c.*2104C>A | 3'UTR (SNP) | VAF 54/147 reads (37%) | called by muse, mutect2, varscan2
- CNTLN | c.1146+55A>G | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- COL11A1 | c.*1114T>G | 3'UTR (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
- CSNK1G1 | c.*449G>A | 3'UTR (SNP) | VAF 15/80 reads (19%) | catalogued as rs1283202902; called by muse, mutect2, varscan2
- CYFIP1 | c.207+127G>A | Intron (SNP) | VAF 31/135 reads (23%) | called by muse, mutect2, varscan2
- DNAJA1 | c.*393A>G | 3'UTR (SNP) | VAF 75/262 reads (29%) | called by muse, mutect2, varscan2
- EIF3J | c.*221A>G | 3'UTR (SNP) | VAF 39/206 reads (19%) | catalogued as rs1377428126; called by muse, mutect2, varscan2
- EVI2A | c.-11+580G>A | Intron (SNP) | VAF 81/167 reads (49%) | called by muse, mutect2, varscan2
- EXOC5 | c.*2245A>G | 3'UTR (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- FAM13A | c.759+772C>T | Intron (SNP) | VAF 89/143 reads (62%) | catalogued as rs1482487031; called by muse, mutect2, varscan2
- FGFR1OP2 | c.*185A>G | 3'UTR (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- GOLGA7B | c.*669C>A | 3'UTR (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- GPR148 | c.*110G>T | 3'UTR (SNP) | VAF 9/131 reads (7%) | called by muse, mutect2
- KCNIP1 | chr5:170736315 G>T | 3'Flank (SNP) | VAF 84/136 reads (62%) | called by muse, mutect2, varscan2
- KIAA1958 | c.*4363T>C | 3'UTR (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- LIN28B | c.*1431del | 3'UTR (DEL) | VAF 8/68 reads (12%) | catalogued as rs1009818775; called by pindel, varscan2
- MDM2 | c.*96T>A | 3'UTR (SNP) | VAF 27/65 reads (42%) | called by muse, varscan2
- MDM2 | c.*251T>A | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, varscan2
- NOL4L | c.*3036A>C | 3'UTR (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- OR10D3 | c.*34T>C | 3'UTR (SNP) | VAF 11/265 reads (4%) | called by muse, mutect2
- PCDH15 | c.*1920A>G | 3'UTR (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- PTRH2 | c.1-2040C>T | Intron (SNP) | VAF 4/60 reads (7%) | catalogued as rs1051033069; called by muse, mutect2
- RC3H2 | c.*2476T>C | 3'UTR (SNP) | VAF 37/150 reads (25%) | called by muse, mutect2, varscan2
- RHOU | c.*1218dup | 3'UTR (INS) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- RNF212 | c.-33G>A | 5'UTR (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- SGK1 | c.152+29C>T | Intron (SNP) | VAF 63/97 reads (65%) | catalogued as rs375352335; called by muse, mutect2, varscan2
- SHH | c.*1941G>A | 3'UTR (SNP) | VAF 13/338 reads (4%) | called by muse, mutect2
- SLCO3A1 | c.*1625G>A | 3'UTR (SNP) | VAF 25/171 reads (15%) | called by muse, mutect2, varscan2
- TAS2R5 | c.-38C>A | 5'UTR (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- TMEM132E | chr17:34575086 T>C | 5'Flank (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- TMEM9B | c.*238dup | 3'UTR (INS) | VAF 32/61 reads (52%) | called by mutect2, pindel, varscan2
- TNFSF11 | c.*947dup | 3'UTR (INS) | VAF 4/34 reads (12%) | catalogued as rs200198391; called by pindel, varscan2
- TUSC1 | c.*92C>T | 3'UTR (SNP) | VAF 27/123 reads (22%) | catalogued as rs988747071; called by muse, mutect2, varscan2
- VGLL3 | c.*3996A>T | 3'UTR (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- WDR86 | c.-65C>T | 5'UTR (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- WNK2 | chr9:93318691 G>A | 3'Flank (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- ZNF583 | chr19:56425473 G>T | 3'Flank (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- ZNF704 | c.*10486dup | 3'UTR (INS) | VAF 34/38 reads (89%) | catalogued as rs201112874; called by mutect2, varscan2
